Somatic mutation profile of tumor specimen ALCH-B4BS-TTP1-A (aliquot ALCH-B4BS-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B4BS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,011 days).
Specimen ALCH-B4BS-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 085d1a58-a96d-43e9-ac6a-d2dc94273508.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4BS-NB1-A (Blood Derived Normal), aliquot ALCH-B4BS-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9595ec63-de50-448e-8094-f512b3b21c0e

The open-access MAF lists 144 somatic variants for this specimen: 101 protein-altering or splice-affecting, 23 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 23, Intron 10, Nonsense Mutation 6, Splice Site 5, 5'Flank 3, RNA 3, 5'UTR 2, Splice Region 1, 3'UTR 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 44/415 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV52642987; called by muse, mutect2, varscan2
- ADAM28 | c.150+1G>T p.X50_splice | Splice Site (SNP) | VAF 13/185 reads (7%) | catalogued as rs1439286933; called by muse, mutect2
- ADGRB1 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60103669; called by muse, mutect2
- ATM | c.7237A>G p.K2413E | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV53778560, COSV99589229; called by muse, mutect2
- C12orf66 | c.136A>T p.S46C | Missense Mutation (SNP) | VAF 28/553 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV100320483; called by muse, mutect2
- CCDC85A | c.1520G>T p.S507I | Missense Mutation (SNP) | VAF 15/369 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV68154254; called by muse, mutect2
- CEP128 | c.2734G>T p.E912* | Nonsense Mutation (SNP) | VAF 30/663 reads (5%) | catalogued as COSV55374328; called by muse, mutect2
- CNPY4 | c.586T>G p.C196G | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749004980; called by muse, mutect2
- CREB3L2 | c.1269G>T p.V423= | Splice Region (SNP) | VAF 25/468 reads (5%) | catalogued as COSV100381696; called by muse, mutect2
- CYP2S1 | c.1236C>A p.F412L | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59505183; called by muse, mutect2
- FSHR | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1267136553, COSV100438012, COSV58620257; called by muse, mutect2
- GABRA2 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 20/300 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.954); catalogued as COSV62917458; called by muse, mutect2
- GPRIN3 | c.982G>T p.V328F | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV104412124; called by muse, mutect2
- IFI44L | c.691G>T p.V231L | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV100655006; called by muse, mutect2
- LILRB5 | c.1408C>A p.L470M (on ENST00000449561 / NM_001081442.3; = p.L469M on NM_006840.5) | Missense Mutation (SNP) | VAF 22/465 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60254460; called by muse, mutect2
- MADD | c.4429C>T p.R1477C | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141476961, COSV60622912; called by muse, mutect2
- MAN1B1 | c.1894C>T p.R632W | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751469383; called by muse, mutect2, varscan2
- MARF1 | c.4691G>A p.R1564H | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs751737939; called by muse, mutect2
- MKRN3 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1293951635; called by muse, mutect2
- MYOM1 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 25/430 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); catalogued as rs776661300, COSV55284920; ClinVar: uncertain significance; called by muse, mutect2
- N4BP1 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 22/237 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as rs753125536; called by muse, mutect2
- NAALADL2 | c.415G>T p.G139W | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70794590; called by muse, mutect2
- OR2L13 | c.309C>A p.F103L | Missense Mutation (SNP) | VAF 46/562 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV63551739; called by muse, mutect2
- OR6Y1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 33/317 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs886503131; called by muse, mutect2, varscan2
- PCDHA2 | c.1320C>A p.S440R | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.338); catalogued as rs1554119811; called by muse, mutect2
- PCDHGA9 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.563); catalogued as rs1400601984; called by muse, mutect2
- PRAMEF2 | c.1237C>A p.P413T | Missense Mutation (SNP) | VAF 22/668 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53579923; called by muse, mutect2
- PTGDR2 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57124582; called by muse, mutect2
- SF3B2 | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.074); catalogued as rs760204374, COSV100488649; called by muse, mutect2
- SHISA9 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 21/336 reads (6%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.98); catalogued as rs867085962, COSV69635854; called by muse, mutect2
- SLITRK5 | c.1106C>A p.P369Q | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770428337, COSV61523992; called by muse, mutect2
- SMG5 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as rs370569638; called by muse, mutect2
- SSMEM1 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 32/517 reads (6%) | catalogued as rs138051879; called by muse, mutect2
- TLR4 | c.1855C>G p.P619A (on ENST00000355622 / NM_138554.5; = p.P579A on NM_003266.4) | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs1179502477, COSV62923404; called by muse, mutect2, varscan2
- UNC79 | c.1992G>T p.E664D (on ENST00000393151 / NM_001346218.2; = p.E487D on NM_020818.5) | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.969); catalogued as COSV56409049; called by muse, mutect2
- USH2A | c.8783G>T p.G2928V | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.767); catalogued as rs746586128; called by muse, mutect2
- WARS2 | c.755G>T p.R252L | Missense Mutation (SNP) | VAF 48/700 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs765994519, COSV52479178; called by muse, mutect2
- ZBBX | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV99048797; called by muse, mutect2
- ADH1A | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 23/367 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- ASXL1 | c.3071C>T p.T1024I | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- BCL3 | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); called by muse, mutect2
- CARMIL2 | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCDC136 | c.2830G>T p.G944W | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CDK16 | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CEACAM20 | c.1576-2A>T p.X526_splice | Splice Site (SNP) | VAF 16/368 reads (4%) | called by muse, mutect2
- CFAP47 | c.2111C>A p.T704N | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- CMTR2 | c.537A>T p.E179D | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTNAP2 | c.1084-2A>T p.X362_splice | Splice Site (SNP) | VAF 11/282 reads (4%) | called by muse, mutect2
- CREB3L2 | c.1270G>T p.V424L | Missense Mutation (SNP) | VAF 25/470 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.267); called by muse, mutect2
- DNAH8 | c.10596T>A p.N3532K | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH9 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 20/357 reads (6%) | called by muse, mutect2
- EVPL | c.4015del p.E1339Rfs*53 | Frame Shift Del (DEL) | VAF 26/194 reads (13%) | called by mutect2, pindel, varscan2
- EYS | c.748G>T p.G250* | Nonsense Mutation (SNP) | VAF 9/187 reads (5%) | called by muse, mutect2
- FMN1 | c.2444C>T p.P815L (on ENST00000616417 / NM_001277313.2; = p.P592L on NM_001103184.4) | Missense Mutation (SNP) | VAF 32/700 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2
- GDF6 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); called by muse, mutect2
- GEMIN4 | c.1903G>T p.V635L | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.042); called by muse, mutect2
- GRID2 | c.544C>A p.Q182K | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2
- HECW1 | c.1241G>T p.R414I | Missense Mutation (SNP) | VAF 24/535 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); called by muse, mutect2
- KAZN | c.652C>T p.H218Y | Missense Mutation (SNP) | VAF 22/361 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); called by muse, mutect2
- KDM5C | c.4334G>T p.R1445L | Missense Mutation (SNP) | VAF 25/426 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.056); called by muse, mutect2
- LCT | c.2717A>G p.D906G | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.387); called by muse, mutect2
- LINGO3 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- LRCOL1 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 7/123 reads (6%) | PolyPhen probably damaging (0.995); called by muse, mutect2
- LRP4 | c.4171G>A p.D1391N | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2
- MAPK8IP3 | c.1966A>G p.N656D | Missense Mutation (SNP) | VAF 9/169 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2
- MDM2 | c.952A>C p.N318H | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MUC12 | c.2149G>T p.G717C (on ENST00000379442; = p.G574C on NM_001164462.1) | Missense Mutation (SNP) | VAF 58/860 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- MUC16 | c.33527A>C p.E11176A | Missense Mutation (SNP) | VAF 11/351 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2
- MUC19 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2
- MYO9A | c.7103A>T p.E2368V | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NEU4 | c.862C>A p.P288T (on ENST00000391969 / NM_001167602.3; = p.P300T on NM_080741.4) | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NFIL3 | c.509T>G p.M170R | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NUP42 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- OR10Q1 | c.755T>C p.V252A | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- OR10T2 | c.202T>C p.S68P | Missense Mutation (SNP) | VAF 34/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2Y1 | c.794A>T p.Y265F | Missense Mutation (SNP) | VAF 38/203 reads (19%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OSBPL10 | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2
- PLIN1 | c.747G>T p.M249I | Missense Mutation (SNP) | VAF 30/373 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.053); called by muse, mutect2
- PPP2CA | c.576+1G>T p.X192_splice | Splice Site (SNP) | VAF 15/249 reads (6%) | called by muse, mutect2
- PRKACA | c.152G>C p.G51A | Missense Mutation (SNP) | VAF 28/448 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2
- PRR5L | c.83G>C p.S28T | Missense Mutation (SNP) | VAF 18/415 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PRRC2B | c.3458C>T p.S1153F | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PRRC2C | c.3025G>T p.D1009Y (on ENST00000367742; = p.D1007Y on NM_015172.4) | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- PYGM | c.398G>C p.G133A | Missense Mutation (SNP) | VAF 43/615 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAD21L1 | c.742+1G>A p.X248_splice | Splice Site (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- RFX8 | c.1337C>A p.P446H (on ENST00000646446; = p.P375H on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/417 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.436); called by muse, mutect2
- SEC24C | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.293); called by muse, mutect2
- TEX44 | c.535A>G p.N179D | Missense Mutation (SNP) | VAF 22/479 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- TRANK1 | c.5450A>G p.E1817G | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TSPAN17 | c.573G>T p.R191S | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- TTC37 | c.4411A>T p.T1471S | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2
- USH2A | c.8782G>T p.G2928* | Nonsense Mutation (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- VAV3 | c.644A>T p.E215V | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.619); called by muse, mutect2
- VN1R4 | c.654G>T p.R218S | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.272); called by muse, mutect2
- WDR36 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 32/756 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2
- ZHX1 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- ZNF107 | c.772A>G p.N258D | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.101); called by muse, mutect2
- ZNF576 | c.232C>A p.R78S | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.799); called by muse, mutect2
- ZNF611 | c.1307G>T p.S436I | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.116); called by muse, mutect2
- ZNF736 | c.888G>T p.W296C | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- ARHGAP20 | c.3021G>T p.G1007= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- ARHGAP40 | c.846C>A p.V282= | Silent (SNP) | VAF 20/352 reads (6%) | called by muse, mutect2
- FYB1 | c.534G>C p.G178= | Silent (SNP) | VAF 26/405 reads (6%) | catalogued as COSV60954096; called by muse, mutect2
- GATA4 | c.864C>T p.G288= | Silent (SNP) | VAF 50/786 reads (6%) | catalogued as rs781143539; called by muse, mutect2
- GCNT1 | c.576G>T p.R192= | Silent (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- GDI1 | c.627C>T p.I209= | Silent (SNP) | VAF 35/456 reads (8%) | catalogued as rs1404103846; called by muse, mutect2
- NRBP2 | c.876C>A p.A292= | Silent (SNP) | VAF 23/282 reads (8%) | called by muse, mutect2
- OR52K2 | c.606C>T p.I202= | Silent (SNP) | VAF 19/278 reads (7%) | catalogued as rs569235087, COSV57834566; called by muse, mutect2
- OR5AU1 | c.762A>T p.T254= | Silent (SNP) | VAF 18/180 reads (10%) | called by muse, mutect2
- OR9G1 | c.285C>T p.G95= | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as rs780745384, COSV100380236; called by muse, mutect2
- OTC | c.537C>A p.L179= | Silent (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- POLR2B | c.414A>G p.E138= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- POTEI | c.2250A>G p.K750= | Silent (SNP) | VAF 18/987 reads (2%) | called by muse, mutect2
- RBM6 | c.3111T>C p.T1037= | Silent (SNP) | VAF 12/262 reads (5%) | called by muse, mutect2
- SARM1 | c.1224C>G p.S408= | Silent (SNP) | VAF 12/217 reads (6%) | catalogued as COSV50229315; called by muse, mutect2
- TACC2 | c.2070G>T p.G690= | Silent (SNP) | VAF 27/290 reads (9%) | called by muse, mutect2
- TBL2 | c.753A>T p.P251= | Silent (SNP) | VAF 26/417 reads (6%) | called by muse, mutect2
- TNR | c.3180C>A p.S1060= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- TPGS1 | c.456G>T p.R152= | Silent (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- UBAP2L | c.2700G>T p.P900= | Silent (SNP) | VAF 47/504 reads (9%) | catalogued as COSV55173599; called by muse, mutect2
- USH2A | c.13413T>C p.N4471= | Silent (SNP) | VAF 52/564 reads (9%) | called by muse, mutect2
- ZNF155 | c.1377G>A p.K459= | Silent (SNP) | VAF 37/435 reads (9%) | catalogued as rs1276886726; called by muse, mutect2
- ZNF626 | c.1563T>A p.P521= | Silent (SNP) | VAF 14/398 reads (4%) | called by muse, mutect2
- AC011487.2 | n.1063G>T | RNA (SNP) | VAF 17/341 reads (5%) | called by muse, mutect2
- AC112721.1 | n.312C>T | RNA (SNP) | VAF 16/215 reads (7%) | called by muse, mutect2
- AC244517.10 | c.36-10461G>C | Intron (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- ACBD7 | c.*6A>T | 3'UTR (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- ARHGEF4 | chr2:130915371 C>A | 5'Flank (SNP) | VAF 16/188 reads (9%) | catalogued as rs961249080; called by muse, mutect2
- C16orf91 | c.-14G>A | 5'UTR (SNP) | VAF 9/171 reads (5%) | catalogued as rs1267291555; called by muse, mutect2
- COL22A1 | c.1758+38C>A | Intron (SNP) | VAF 26/225 reads (12%) | called by muse, mutect2, varscan2
- COL22A1 | c.1758+37C>A | Intron (SNP) | VAF 25/217 reads (12%) | called by muse, mutect2, varscan2
- DYNLRB2 | c.-21C>A | 5'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, mutect2, varscan2
- FBRS | chr16:30662486 G>T | 5'Flank (SNP) | VAF 18/266 reads (7%) | called by muse, mutect2
- HELZ2 | c.570+116G>T | Intron (SNP) | VAF 38/496 reads (8%) | called by muse, mutect2
- LAMB3 | c.2358+28C>T | Intron (SNP) | VAF 37/740 reads (5%) | called by muse, mutect2
- MIR509-1 | n.64C>G | RNA (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- MMP8 | c.103-396G>C | Intron (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2
- NCDN | chr1:35557763 G>T | 5'Flank (SNP) | VAF 18/230 reads (8%) | called by muse, mutect2
- NFASC | c.2471-1406C>A | Intron (SNP) | VAF 50/582 reads (9%) | catalogued as COSV58361008; called by muse, mutect2
- RGMA | c.15-699G>T | Intron (SNP) | VAF 29/217 reads (13%) | called by muse, mutect2
- SKP2 | c.1062-1595A>T | Intron (SNP) | VAF 11/85 reads (13%) | called by mutect2, varscan2
- SORCS1 | c.3371+227C>A | Intron (SNP) | VAF 26/431 reads (6%) | called by muse, mutect2
- TUT1 | chr11:62574762 A>G | 3'Flank (SNP) | VAF 31/633 reads (5%) | called by muse, mutect2
